Somatic mutation profile of tumor specimen 0DEFJY from CCDI case PBBNZL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.0 years (5,846 days).
Specimen 0DEFJY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38874bb0-8ac1-4fe7-9352-ffc279e6fe79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEFHQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b48dae-7025-4d2d-97a9-241e93b9b354

The open-access MAF lists 844 somatic variants for this specimen: 531 protein-altering or splice-affecting, 165 silent, 148 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 404, Silent 165, Intron 93, Frame Shift Del 52, 3'UTR 34, Nonsense Mutation 27, Frame Shift Ins 27, Splice Region 16, 5'UTR 15, RNA 3, Splice Site 2, In Frame Del 2.

Variants (750 of 844; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG12 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 274/659 reads (42%) | PolyPhen probably damaging (0.998); catalogued as rs121907931, CM022080, COSV58208429; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.4414C>T p.R1472* (on ENST00000646647 / NM_001170629.2; = p.R1193* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 157/1531 reads (10%) | catalogued as rs991738444, COSV63219638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HIVEP2 | c.6667C>T p.R2223* | Nonsense Mutation (SNP) | VAF 421/855 reads (49%) | catalogued as rs1562493608, COSV99176544; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 141/1356 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 76/644 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1064795070, COSV53025487, COSV53045576; ClinVar: likely pathogenic; called by muse, varscan2
- PTCH1 | c.114del p.L39Cfs*41 | Frame Shift Del (DEL) | VAF 144/467 reads (31%) | catalogued as rs751977093; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 108/838 reads (13%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 473/1151 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 399/943 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 253/610 reads (41%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1279378344; called by muse, mutect2, varscan2
- AASDHPPT | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 671/1644 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs769999593, COSV53788350; called by muse, mutect2, varscan2
- ABCA2 | c.3227C>T p.S1076L (on ENST00000614293; = p.S1046L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 331/810 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs369448216; called by muse, mutect2, varscan2
- ABCC3 | c.3875G>A p.R1292Q | Missense Mutation (SNP) | VAF 423/1036 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs140585197; called by muse, mutect2, varscan2
- ABCD3 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 324/1452 reads (22%) | catalogued as rs1313259003; called by muse, mutect2, varscan2
- ABHD16B | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 103/526 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1486893684; called by muse, mutect2
- AC013489.1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 310/668 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs373214566, COSV51549905; called by muse, mutect2, varscan2
- ACE | c.2593G>A p.G865R | Missense Mutation (SNP) | VAF 237/927 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs939884644; called by muse, mutect2, varscan2
- ADA2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 253/1084 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.127); catalogued as rs545602214, COSV52830634; ClinVar: uncertain significance; called by mutect2, varscan2
- ADAMTS10 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 149/614 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1188791985, COSV99546735; called by muse, mutect2, varscan2
- ADARB1 | c.2033G>A p.R678H (on ENST00000360697 / NM_001346687.2; = p.R638H on NM_001112.4) | Missense Mutation (SNP) | VAF 78/1156 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as rs762560636, COSV100653872; called by muse, mutect2
- AGBL3 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 473/1147 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs377484969; called by muse, mutect2, varscan2
- AJAP1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 366/876 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as rs199545288, COSV65450500; called by muse, mutect2, varscan2
- AK9 | c.2097del p.E700Kfs*13 | Frame Shift Del (DEL) | VAF 94/168 reads (56%) | catalogued as rs753010985; called by mutect2, varscan2
- AKT2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 146/1424 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs775105991, COSV100251832; called by muse, mutect2, varscan2
- ANKEF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 267/2073 reads (13%) | catalogued as rs774211930, COSV65691928; called by muse, mutect2, varscan2
- AP002512.3 | c.393dup p.V132Cfs*22 | Frame Shift Ins (INS) | VAF 514/1748 reads (29%) | catalogued as rs775245123; called by mutect2, varscan2
- APC2 | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 169/387 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs762097433; called by muse, mutect2, varscan2
- APLP2 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 90/803 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.801); catalogued as rs776991189; called by muse, mutect2, varscan2
- APOB | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 477/1063 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769425660, COSV51938544; called by muse, mutect2, varscan2
- ARHGAP36 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 539/600 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs372524788; called by muse, mutect2, varscan2
- ARHGAP40 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 577/1348 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749710569; called by muse, mutect2, varscan2
- ARHGEF10 | c.1843C>T p.R615C (on ENST00000398564; = p.R590C on NM_014629.4) | Missense Mutation (SNP) | VAF 205/1763 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs141069028; called by muse, mutect2, varscan2
- ARL4C | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 321/698 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60214298; called by muse, mutect2, varscan2
- ARNT2 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 115/440 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs145621152; called by muse, mutect2, varscan2
- ARSJ | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 546/712 reads (77%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as rs753323611; called by muse, mutect2, varscan2
- ASXL3 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 208/1920 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as rs781039611, COSV99325907; called by muse, mutect2, varscan2
- ATF6B | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 455/1126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559716525; called by muse, mutect2, varscan2
- ATG9A | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 319/1216 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs755849358; called by muse, mutect2, varscan2
- ATP6V0D1 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 390/955 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs763981473; called by muse, mutect2, varscan2
- BAZ2A | c.5662C>T p.R1888C | Missense Mutation (SNP) | VAF 540/1283 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs776034004; called by muse, mutect2, varscan2
- BAZ2B | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 767/1954 reads (39%) | catalogued as COSV54276779; called by muse, mutect2, varscan2
- BCL7C | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 154/772 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as rs781611007, COSV99288488; called by muse, mutect2, varscan2
- BCL9L | c.2704G>A p.V902M | Missense Mutation (SNP) | VAF 65/474 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs564056959; called by muse, mutect2, varscan2
- BTBD18 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 103/1002 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs903818754, COSV53554824; called by muse, mutect2, varscan2
- BTBD3 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 511/1197 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as rs149470256; called by muse, mutect2, varscan2
- C14orf39 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 104/1192 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs1314714821; called by muse, mutect2
- C17orf97 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 170/1296 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs782695210, COSV100789309, COSV100789356; called by muse, mutect2, varscan2
- C22orf23 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 129/1278 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs143633550; called by muse, mutect2, varscan2
- C7 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 208/1852 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772464175, COSV100496447; called by muse, mutect2, varscan2
- C9orf78 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 66/1133 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs759835798; called by muse, mutect2
- CA7 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 382/847 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs201416423; called by muse, mutect2, varscan2
- CADPS | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 781/1973 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs374035152; called by muse, mutect2, varscan2
- CARD11 | c.2918G>A p.R973H | Missense Mutation (SNP) | VAF 82/802 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs141681466, COSV67796624; called by muse, varscan2
- CASP8AP2 | c.3859C>T p.R1287* | Nonsense Mutation (SNP) | VAF 676/1602 reads (42%) | catalogued as COSV52745590; called by muse, mutect2, varscan2
- CCDC175 | c.1895dup p.N632Kfs*6 | Frame Shift Ins (INS) | VAF 173/1450 reads (12%) | catalogued as rs1198843594; called by mutect2, varscan2
- CDC25B | c.423C>T p.N141= (on ENST00000245960 / NM_021873.3; = p.N127= on NM_004358.4) | Splice Region (SNP) | VAF 357/850 reads (42%) | catalogued as rs756726870; called by muse, mutect2, varscan2
- CDH9 | c.2026A>G p.T676A | Missense Mutation (SNP) | VAF 486/1977 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as rs745394195; called by muse, mutect2, varscan2
- CDKN2A | c.225del p.A76Pfs*70 | Frame Shift Del (DEL) | VAF 426/535 reads (80%) | catalogued as COSV58683530, COSV58692257; called by mutect2, varscan2
- CEP162 | c.4153C>T p.R1385W | Missense Mutation (SNP) | VAF 130/2094 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs78654567; called by muse, mutect2
- CEP85 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 231/980 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as rs143208344; called by muse, mutect2, varscan2
- CETN1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 150/1596 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs139897799, COSV100511432; called by muse, mutect2
- CFAP157 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 466/1093 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200089194; called by muse, mutect2, varscan2
- CFAP77 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 87/591 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138982113; called by muse, mutect2, varscan2
- CGN | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 196/1331 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs762594587, COSV54969427; called by muse, mutect2, varscan2
- CHAD | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 71/611 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1170674120, COSV51973659; called by muse, mutect2, varscan2
- CHD4 | c.2411G>A p.R804Q (on ENST00000357008 / NM_001363606.2; = p.R817Q on NM_001273.5) | Missense Mutation (SNP) | VAF 124/1592 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775293840, COSV58898389; called by muse, mutect2
- CHFR | c.1276G>A p.V426I (on ENST00000432561 / NM_001161345.1; = p.V385I on NM_018223.2) | Missense Mutation (SNP) | VAF 60/938 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768814594; called by muse, mutect2
- CHRD | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 181/471 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1361960633; called by muse, mutect2, varscan2
- CHRNA10 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 242/887 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs369800306, COSV51709209; called by muse, mutect2, varscan2
- CHRNB2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 362/839 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1440128191; called by muse, mutect2, varscan2
- CIR1 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 193/1362 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs762930010, COSV59597591; called by muse, mutect2, varscan2
- CNKSR1 | c.788G>A p.R263H (on ENST00000374253 / NM_001297647.2; = p.R256H on NM_006314.3) | Missense Mutation (SNP) | VAF 149/361 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs139571283; called by muse, mutect2, varscan2
- CNPPD1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 38/578 reads (7%) | catalogued as rs780689902; called by muse, mutect2
- COL12A1 | c.8236G>A p.V2746I | Missense Mutation (SNP) | VAF 623/1532 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as rs374979813; called by muse, mutect2, varscan2
- COL6A3 | c.6529G>A p.G2177S | Missense Mutation (SNP) | VAF 136/978 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773235743; called by muse, mutect2, varscan2
- COL6A6 | c.*5del | Frame Shift Del (DEL) | VAF 87/774 reads (11%) | catalogued as rs747090655; called by mutect2, varscan2
- CPEB2 | c.1239_1244del p.Q418_P419del | In Frame Del (DEL) | VAF 932/1372 reads (68%) | catalogued as rs1229248435; called by mutect2, varscan2
- CPNE7 | c.335dup p.M113Hfs*23 | Frame Shift Ins (INS) | VAF 172/416 reads (41%) | catalogued as rs775398112; called by mutect2, varscan2
- CTCF | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 82/1571 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as rs760093869; called by muse, mutect2
- CYP2F1 | c.1152+4C>T | Splice Region (SNP) | VAF 137/941 reads (15%) | catalogued as rs1370992858; called by muse, mutect2, varscan2
- DBNL | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 71/500 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765831487; called by muse, mutect2, varscan2
- DGAT1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 411/969 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781969331; called by muse, mutect2, varscan2
- DGKI | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 409/988 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs778003452, COSV55940907; called by muse, mutect2, varscan2
- DHX37 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 384/847 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764894461; called by muse, mutect2, varscan2
- DLK2 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs371794983; called by muse, mutect2, varscan2
- DNAH1 | c.7066C>T p.R2356W | Missense Mutation (SNP) | VAF 406/980 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780050981; called by muse, mutect2, varscan2
- DNAH10 | c.1129C>T p.L377F (on ENST00000409039; = p.L316F on NM_207437.3) | Missense Mutation (SNP) | VAF 497/1238 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1297771722; called by muse, mutect2, varscan2
- DNAH5 | c.9976G>A p.V3326I | Missense Mutation (SNP) | VAF 836/1954 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs149452082; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 660/1530 reads (43%) | catalogued as rs761292636; called by mutect2, varscan2
- DNPEP | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 334/790 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752354962; called by muse, mutect2, varscan2
- DOCK8 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 857/1051 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs374938180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOP1B | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 429/1079 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747145267; called by muse, mutect2, varscan2
- DPH1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 120/924 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373627981; called by muse, mutect2, varscan2
- DPP7 | c.1205dup p.D403* | Frame Shift Ins (INS) | VAF 136/352 reads (39%) | catalogued as rs748560644; called by mutect2, varscan2
- DPP8 | c.2243G>A p.R748H (on ENST00000341861 / NM_001320875.2; = p.R732H on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 251/997 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438259659, COSV55685171; called by muse, mutect2, varscan2
- DTYMK | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 380/975 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs768172745; called by muse, mutect2
- DUSP3 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 405/908 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs762020568; called by muse, mutect2, varscan2
- EFCAB2 | c.754G>A p.E252K (on ENST00000366522; = p.E116K on NM_032328.3) | Missense Mutation (SNP) | VAF 438/1215 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs778803377, COSV63658920; called by muse, mutect2, varscan2
- EIF2AK4 | c.4426C>T p.R1476C | Missense Mutation (SNP) | VAF 246/1556 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1161134551, COSV55467484; called by muse, mutect2, varscan2
- EIF3A | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 635/790 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs375737679; called by muse, mutect2, varscan2
- EIF3K | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 234/624 reads (38%) | catalogued as rs375893694; called by muse, varscan2
- ELMO1 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 925/2251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs781351975, COSV60296432; called by muse, mutect2, varscan2
- EML6 | c.4522C>T p.R1508C | Missense Mutation (SNP) | VAF 97/827 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs750197361, COSV62872545; called by muse, mutect2, varscan2
- ENG | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 70/529 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs758012489; called by muse, mutect2, varscan2
- ENTPD4 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 433/836 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs971814133, COSV62270798; called by muse, mutect2, varscan2
- EPN3 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 130/1070 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753177479, COSV52139195; called by muse, mutect2, varscan2
- ERC1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 946/1718 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773843924, COSV61698092; called by muse, varscan2
- ERVH48-1 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 291/560 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as rs1164539501; called by muse, mutect2, varscan2
- EVC | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 1828/2466 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769614620; called by muse, mutect2, varscan2
- EVPL | c.5190del p.C1732Vfs*49 | Frame Shift Del (DEL) | VAF 122/308 reads (40%) | catalogued as COSV56915647; called by mutect2, varscan2
- EXOC6B | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 176/1724 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs756368454, COSV55555100; called by muse, varscan2
- FADS2 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 381/873 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750796701, COSV53897550; called by muse, mutect2, varscan2
- FAM189A1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 136/543 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768291963; called by muse, mutect2, varscan2
- FARP1 | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 189/261 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs769331960; called by muse, mutect2, varscan2
- FBXL13 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 709/1723 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1362026713, COSV57538408; called by muse, mutect2, varscan2
- FGR | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 379/901 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371077484; called by muse, mutect2, varscan2
- FRRS1 | c.611G>A p.C204Y | Missense Mutation (SNP) | VAF 674/1664 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746062633; called by muse, mutect2, varscan2
- FSCB | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 124/1142 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs866751776; called by mutect2, varscan2
- FSIP2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 200/2354 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs761028361, COSV58083632; called by muse, mutect2
- FUT8 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 136/2438 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs763886677; called by muse, mutect2
- GALNTL6 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 760/959 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72490982; called by muse, mutect2, varscan2
- GJB7 | c.651dup p.P218Tfs*40 | Frame Shift Ins (INS) | VAF 708/1740 reads (41%) | catalogued as rs775175904; called by mutect2, varscan2
- GNRH2 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 380/801 reads (47%) | catalogued as rs144772130, COSV55661865; called by muse, mutect2, varscan2
- GOLIM4 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 469/1177 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.528); catalogued as rs144800331; called by muse, mutect2, varscan2
- GPA33 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 652/1539 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs747670451, COSV63300386, COSV63300512; called by muse, mutect2, varscan2
- GPR132 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 227/495 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs778634514, COSV61678424; called by muse, mutect2, varscan2
- GPR162 | c.1579C>T p.R527W (on ENST00000311268 / NM_019858.2; = p.R243W on NM_014449.2) | Missense Mutation (SNP) | VAF 45/478 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs782038710; called by muse, mutect2
- GRID2IP | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 439/1087 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1010698514; called by muse, mutect2, varscan2
- GTF2B | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 461/1031 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as rs769046476, COSV100980563; called by muse, mutect2, varscan2
- GTF2IRD2B | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 223/1172 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.965); catalogued as rs781944066, COSV57032448; called by muse, mutect2, varscan2
- GTF3C5 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 46/864 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs564242923, COSV59599185; called by muse, mutect2
- HEPHL1 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 232/994 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs200632347; called by muse, mutect2, varscan2
- HLA-DRA | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 504/1456 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV66622802; called by muse, mutect2
- HMCN1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 588/1451 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs531770127, COSV54903513; called by muse, mutect2, varscan2
- HORMAD1 | c.848A>C p.N283T | Missense Mutation (SNP) | VAF 686/1792 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs45439605; called by mutect2, varscan2
- HOXD8 | c.329dup p.P111Sfs*31 | Frame Shift Ins (INS) | VAF 102/290 reads (35%) | catalogued as rs770632206; called by mutect2, varscan2
- HPR | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 416/822 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs760913553; called by muse, mutect2, varscan2
- HPSE | c.1596dup p.V533Cfs*46 | Frame Shift Ins (INS) | VAF 646/821 reads (79%) | catalogued as rs777639789; called by mutect2, varscan2
- HRH1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 147/614 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs201947424, COSV67955106; called by muse, mutect2, varscan2
- HSPB1 | c.438del p.G147Vfs*17 | Frame Shift Del (DEL) | VAF 320/749 reads (43%) | catalogued as rs747325717; called by mutect2, varscan2
- HSPB9 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 219/629 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as COSV56790580; called by muse, mutect2, varscan2
- HSPG2 | c.9539C>T p.A3180V | Missense Mutation (SNP) | VAF 89/842 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs748710241, COSV65933465; called by muse, mutect2, varscan2
- HTRA2 | c.346dup p.A116Gfs*22 | Frame Shift Ins (INS) | VAF 204/560 reads (36%) | catalogued as rs779457274; called by mutect2, varscan2
- HUWE1 | c.7808G>A p.R2603Q | Missense Mutation (SNP) | VAF 103/535 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); catalogued as rs146149373, COSV53345431; called by muse, mutect2, varscan2
- HYDIN | c.7837G>A p.A2613T | Missense Mutation (SNP) | VAF 264/1181 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs201369863, COSV59264388; called by muse, mutect2
- IFI27 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 405/916 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs752772349; called by muse, mutect2, varscan2
- IFT140 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 281/709 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147756729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF2R | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 689/1614 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs778725774, COSV63626464; called by muse, mutect2, varscan2
- IGFALS | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 58/442 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.825); catalogued as rs544452737; called by muse, mutect2, varscan2
- IGFN1 | c.3434C>A p.A1145D (on ENST00000295591 / NM_001367841.1; = p.A3602D on NM_001164586.2) | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV99811315; called by muse, mutect2, varscan2
- INTS11 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 73/632 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173991453, COSV60088840; called by muse, mutect2, varscan2
- IPMK | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 392/805 reads (49%) | catalogued as rs758099009, COSV100880207; called by muse, mutect2, varscan2
- ISYNA1 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 105/563 reads (19%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs765234659; called by muse, mutect2, varscan2
- ITGA2B | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 199/530 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867277020; called by muse, mutect2, varscan2
- ITGA3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 354/863 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs368933755; called by muse, mutect2, varscan2
- ITGA7 | c.2870G>A p.R957Q (on ENST00000555728; = p.R913Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 470/1088 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as rs755263823, COSV99153483; called by muse, mutect2, varscan2
- JUND | c.252del p.D85Tfs*12 | Frame Shift Del (DEL) | VAF 100/356 reads (28%) | catalogued as rs1555702626, COSV53254483; called by mutect2, varscan2
- KAT14 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 167/1387 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs754595069; called by muse, mutect2, varscan2
- KCNH1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 308/1075 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763802122, COSV55080194; called by muse, mutect2, varscan2
- KMT2D | c.7831C>T p.R2611C | Missense Mutation (SNP) | VAF 48/590 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs572359740, COSV56452968; called by muse, mutect2
- KPRP | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 331/772 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs768811278, COSV100908839, COSV64222051; called by muse, mutect2, varscan2
- KRBA1 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 111/840 reads (13%) | catalogued as rs767829963; called by muse, mutect2, varscan2
- KRT15 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 89/640 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs139367098; called by muse, mutect2, varscan2
- KRT73 | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 345/828 reads (42%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.053); catalogued as rs199933409, COSV59839786; called by muse, mutect2, varscan2
- KRT73 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 511/1259 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs146681578; called by muse, mutect2, varscan2
- LAMA4 | c.5380C>T p.R1794C (on ENST00000230538 / NM_001105206.3; = p.R1787C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 777/1788 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781802725, COSV57895259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.9112C>T p.R3038C | Missense Mutation (SNP) | VAF 263/647 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371420868; called by muse, mutect2, varscan2
- LBR | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 540/1416 reads (38%) | catalogued as rs1057516045, COSV55287340; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- LCK | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 484/1073 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs771899555; called by muse, mutect2, varscan2
- LCOR | c.2574dup p.E859Rfs*10 | Frame Shift Ins (INS) | VAF 176/800 reads (22%) | catalogued as rs1361355752; called by mutect2, varscan2
- LDHB | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 862/1986 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs745737131; called by muse, mutect2, varscan2
- LDLR | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 603/1333 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs768563000, CM055368, CM920426, COSV52943107; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LHCGR | c.50_52dup p.L17dup | In Frame Ins (INS) | VAF 98/634 reads (15%) | catalogued as rs1553401008; called by mutect2, varscan2
- LILRB2 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 142/448 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs779866193; called by muse, mutect2
- LINGO4 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 312/825 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs370036064; called by muse, mutect2, varscan2
- LLGL1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 331/746 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs755966163; called by muse, mutect2, varscan2
- LMCD1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 422/1027 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as rs768404180, COSV50088367; called by muse, varscan2
- LMTK2 | c.4078G>A p.D1360N | Missense Mutation (SNP) | VAF 404/1016 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1258701205; called by muse, mutect2, varscan2
- LPL | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 526/1348 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.298); catalogued as rs298, CM1213431, COSV60930454; called by muse, mutect2, varscan2
- LRCH4 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 69/644 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs369164222; called by mutect2, varscan2
- LYZ | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 758/1832 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs1412678115; called by muse, mutect2, varscan2
- LZTS2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 99/497 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771145732, COSV64651119; called by muse, mutect2, varscan2
- MADD | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 373/875 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs181204693; called by muse, mutect2, varscan2
- MAL2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 790/2030 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs774346762, COSV99411237; called by muse, mutect2, varscan2
- MANSC1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 214/442 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770162136, CM125539, COSV67111542; called by muse, mutect2, varscan2
- MAP7D2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 576/637 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1342772059; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 386/955 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs753108871, COSV51727761; called by muse, mutect2, varscan2
- MCOLN2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 690/1625 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs201171839, COSV52295381; called by muse, mutect2, varscan2
- MEAF6 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 64/1850 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV56162605, COSV56163847; called by muse, mutect2
- MED27 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 208/553 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1564256623; called by muse, mutect2, varscan2
- MEGF8 | c.2644G>A p.G882R (on ENST00000251268 / NM_001271938.2; = p.G815R on NM_001410.3) | Missense Mutation (SNP) | VAF 129/672 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs147068787; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 63/378 reads (17%) | catalogued as rs762448666; called by mutect2, varscan2
- MIOS | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 681/1656 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs755747521, COSV60767908; called by muse, mutect2, varscan2
- MKRN2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 368/1326 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs748060166; called by muse, mutect2, varscan2
- MME | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 447/1795 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs199804325, COSV64707147; called by muse, mutect2, varscan2
- MMP2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 414/902 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs371671100; called by muse, varscan2
- MN1 | c.3358G>A p.G1120S | Missense Mutation (SNP) | VAF 245/606 reads (40%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.009); catalogued as rs1277193009; called by muse, mutect2, varscan2
- MON2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 283/2043 reads (14%) | catalogued as rs1424459395, COSV54804809; called by muse, mutect2, varscan2
- MRC2 | c.3434G>A p.R1145H | Missense Mutation (SNP) | VAF 290/642 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as rs774190435; called by muse, mutect2, varscan2
- MRPS18C | c.150+16del | Splice Region (DEL) | VAF 430/568 reads (76%) | catalogued as rs199634680; called by mutect2, varscan2
- MRPS30 | c.972del p.F324Lfs*37 | Frame Shift Del (DEL) | VAF 194/1776 reads (11%) | catalogued as rs764773638; called by mutect2, varscan2
- MUC4 | c.15316C>T p.R5106W (on ENST00000463781 / NM_018406.7; = p.R870W on NM_004532.6) | Missense Mutation (SNP) | VAF 447/1078 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1338980774, COSV100203573; called by muse, mutect2, varscan2
- MYBBP1A | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 288/667 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs779307309; called by muse, mutect2, varscan2
- MYH6 | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 133/1234 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368912844; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK3 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 370/1081 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs192689311, COSV101189093; called by muse, mutect2, varscan2
- MYO18A | c.4225C>T p.R1409W | Missense Mutation (SNP) | VAF 294/692 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751766555; called by muse, mutect2, varscan2
- MYO18A | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 378/920 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs368317817; called by muse, mutect2, varscan2
- MYO1G | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 351/706 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs747419960; called by muse, mutect2, varscan2
- MYT1 | c.2587C>T p.R863W | Missense Mutation (SNP) | VAF 335/718 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100115091; called by muse, mutect2, varscan2
- N4BP2 | c.3778A>G p.K1260E | Missense Mutation (SNP) | VAF 192/4113 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs745902465; called by muse, mutect2
- NAA25 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 216/1624 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1440914818; called by muse, mutect2, varscan2
- NANOS3 | c.307G>A p.A103T (on ENST00000397555; = p.A122T on NM_001098622.2) | Missense Mutation (SNP) | VAF 172/416 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310054421, COSV100188538; called by muse, mutect2, varscan2
- NCOR2 | c.3647G>A p.R1216Q | Missense Mutation (SNP) | VAF 85/1090 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs377739293; called by muse, mutect2
- NDUFA10 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 130/1208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230530438, COSV53152467, COSV53155891; called by muse, mutect2, varscan2
- NEB | c.14282C>T p.P4761L | Missense Mutation (SNP) | VAF 668/1625 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369054525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIBAN1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 73/689 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100836281; called by muse, mutect2, varscan2
- NKX2-2 | c.370del p.D124Tfs*60 | Frame Shift Del (DEL) | VAF 272/682 reads (40%) | catalogued as rs752776917; called by mutect2, varscan2
- NLK | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 85/2058 reads (4%) | catalogued as COSV101311357; called by muse, mutect2
- NOL7 | c.714del p.K238Nfs*16 | Frame Shift Del (DEL) | VAF 345/916 reads (38%) | catalogued as rs544905440; called by mutect2, varscan2
- NPIPB2 | c.1106G>A p.R369Q (on ENST00000399147; = p.R229Q on NM_001355514.1) | Missense Mutation (SNP) | VAF 87/575 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.025); catalogued as rs771760925, COSV100604891; called by muse, mutect2, varscan2
- NPIPB6 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 93/428 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.602); catalogued as rs562943286; called by muse, mutect2, varscan2
- NPR2 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 357/869 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs1192585936, COSV61309328; called by muse, varscan2
- NPR2 | c.2833C>T p.R945C | Missense Mutation (SNP) | VAF 232/924 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs781398693, COSV52413992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5DC1 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 624/1579 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241122736; called by muse, mutect2, varscan2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 306/661 reads (46%) | catalogued as rs754390000; called by mutect2, varscan2
- OBSCN | c.6890G>A p.R2297Q | Missense Mutation (SNP) | VAF 575/1378 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.435); catalogued as rs747671426; called by muse, mutect2, varscan2
- OGFOD1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 151/1474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535053365; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 498/617 reads (81%) | catalogued as rs753966040; called by mutect2, varscan2
- OS9 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 310/673 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs149723570; called by muse, mutect2, varscan2
- OSBPL7 | c.2184del p.D729Tfs*15 | Frame Shift Del (DEL) | VAF 90/624 reads (14%) | catalogued as rs1567937897, COSV50107065; called by mutect2, varscan2
- OTUD7B | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 83/1500 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as rs200022303, COSV64918439; called by muse, mutect2
- OXER1 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 244/624 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs374132247; called by muse, mutect2, varscan2
- PAXIP1 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 177/1655 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs778190585; called by muse, mutect2, varscan2
- PCDHA4 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 46/1162 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as rs782621345, COSV63545257; called by muse, mutect2
- PDE11A | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 120/1040 reads (12%) | catalogued as rs762405282, COSV53687790; called by muse, mutect2, varscan2
- PGF | c.73dup p.Q25Pfs*66 | Frame Shift Ins (INS) | VAF 137/372 reads (37%) | catalogued as rs756979630; called by mutect2, varscan2
- PHF20 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 499/1197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144252568; called by muse, mutect2, varscan2
- PIEZO1 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 162/345 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs977853784; called by muse, mutect2, varscan2
- PITPNM2 | c.3800C>T p.T1267M | Missense Mutation (SNP) | VAF 103/594 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1396965627; called by muse, mutect2, varscan2
- PIWIL3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 115/1067 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs775437461, COSV59994528; called by muse, mutect2, varscan2
- PKD1L2 | n.1371C>T | Splice Region (SNP) | VAF 321/733 reads (44%) | catalogued as rs200846553; called by muse, mutect2, varscan2
- PLA2R1 | c.2594C>T p.A865V | Missense Mutation (SNP) | VAF 433/960 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs754388194; called by muse, mutect2, varscan2
- PLCG2 | c.3103G>T p.G1035C | Missense Mutation (SNP) | VAF 293/1122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100842319; called by muse, mutect2, varscan2
- PLCH2 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 256/1005 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs748035129, COSV53942604; called by muse, mutect2, varscan2
- PLEC | c.11189C>T p.S3730L (on ENST00000322810 / NM_201380.4; = p.S3620L on NM_000445.5) | Missense Mutation (SNP) | VAF 34/828 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs782707803, COSV59670556; called by muse, mutect2
- PLEC | c.4513G>A p.A1505T (on ENST00000322810 / NM_201380.4; = p.A1395T on NM_000445.5) | Missense Mutation (SNP) | VAF 242/594 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs1554704248; called by muse, mutect2, varscan2
- PLEKHF1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 107/385 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71410042; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 416/517 reads (80%) | catalogued as rs772701630; called by mutect2, varscan2
- PLXNA1 | c.4172C>T p.S1391L | Missense Mutation (SNP) | VAF 314/671 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1275067193; called by muse, mutect2, varscan2
- PNPLA6 | c.2470C>T p.R824C (on ENST00000414982 / NM_001166111.2; = p.R776C on NM_006702.5) | Missense Mutation (SNP) | VAF 405/988 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs531445564, COSV55375072; called by muse, mutect2
- POLR1A | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 430/1036 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1029249129, COSV55696721; called by muse, mutect2, varscan2
- POLR2C | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 366/838 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV54671700; called by muse, mutect2, varscan2
- POMGNT1 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 353/817 reads (43%) | PolyPhen probably damaging (0.973); catalogued as rs769180238, COSV100915571; called by muse, mutect2, varscan2
- POTEM | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 106/518 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs768801095; called by muse, varscan2
- PRICKLE2 | c.2390G>A p.R797Q (on ENST00000295902; = p.R741Q on NM_198859.4) | Missense Mutation (SNP) | VAF 313/724 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.432); catalogued as rs202197921; called by muse, mutect2, varscan2
- PRKACG | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 225/532 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99598786; called by muse, mutect2, varscan2
- PROKR1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 117/862 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1251229546, COSV58138406; called by muse, mutect2, varscan2
- PSPN | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 88/637 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs761239429, COSV55532909; called by muse, mutect2, varscan2
- PTOV1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 348/820 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs760556849; called by muse, mutect2, varscan2
- PTPN23 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 408/921 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs758841754; called by muse, varscan2
- PTPN23 | c.4015C>T p.R1339* | Nonsense Mutation (SNP) | VAF 348/790 reads (44%) | catalogued as rs724159944, COSV55546827; called by muse, mutect2, varscan2
- PWP1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 177/1304 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs556499588; called by muse, mutect2, varscan2
- RADIL | c.2987C>T p.T996M | Missense Mutation (SNP) | VAF 269/633 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1052836249, COSV68200955; called by muse, mutect2, varscan2
- RALGDS | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 200/740 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs753812769, COSV100924441; called by muse, mutect2, varscan2
- RANBP2 | c.6115C>T p.R2039W | Missense Mutation (SNP) | VAF 114/559 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766455181; called by muse, mutect2, varscan2
- RAPGEF4 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 453/1090 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs758218304; called by muse, mutect2, varscan2
- RASGRP2 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 419/939 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs532620789, COSV100818190; called by muse, mutect2, varscan2
- RAX2 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as rs754730849; ClinVar: uncertain significance; called by muse, varscan2
- RBM47 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 213/1496 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs896371394; called by muse, mutect2, varscan2
- RBMY1E | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 97/660 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs757852201; called by muse, mutect2, varscan2
- REPIN1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 178/416 reads (43%) | catalogued as rs1390075812; called by muse, mutect2, varscan2
- RESF1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 567/1350 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.254); catalogued as rs139948313; called by muse, mutect2, varscan2
- RFWD3 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 685/1675 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772951020, COSV63097558; called by muse, mutect2, varscan2
- RFX4 | c.1121G>A p.R374Q (on ENST00000392842 / NM_213594.3; = p.R280Q on NM_032491.6) | Missense Mutation (SNP) | VAF 644/1479 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.921); catalogued as rs761360451, COSV57572533, COSV57577646; called by muse, mutect2, varscan2
- RFX7 | c.1522C>T p.R508C (on ENST00000559447 / NM_001368074.1; = p.R605C on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 280/1105 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs369466675; called by muse, mutect2, varscan2
- RGL2 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 433/1002 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.735); catalogued as rs752386398, COSV65842166; called by muse, mutect2, varscan2
- RIF1 | c.7040G>A p.R2347H | Missense Mutation (SNP) | VAF 780/1996 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99690417; called by muse, mutect2, varscan2
- RMDN2 | c.665G>A p.R222H (on ENST00000354545 / NM_001322212.2; = p.R400H on NM_144713.5) | Missense Mutation (SNP) | VAF 840/2024 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781674953, COSV52230861; called by muse, mutect2, varscan2
- RNGTT | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 387/1059 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335942203; called by muse, mutect2, varscan2
- ROBO2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 134/2100 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1196957436, COSV59895199; called by muse, mutect2
- RPS19BP1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 63/529 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1268081304; called by muse, mutect2, varscan2
- RPS4Y2 | c.11del p.G4Afs*6 | Frame Shift Del (DEL) | VAF 140/192 reads (73%) | catalogued as COSV56488481; called by mutect2, varscan2
- RRP8 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 545/1326 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs763957188, COSV54449610; called by muse, varscan2
- RYR2 | c.3371C>T p.P1124L | Missense Mutation (SNP) | VAF 558/1263 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs779640835, COSV100769203, COSV63662051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.5878A>C p.I1960L | Missense Mutation (SNP) | VAF 296/1657 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.746); catalogued as rs1440505313; called by muse, mutect2, varscan2
- SALL2 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 252/576 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746092722, COSV100444523, COSV58103814; called by muse, mutect2, varscan2
- SATB2 | c.598-4del | Splice Region (DEL) | VAF 256/828 reads (31%) | catalogued as rs199978702; ClinVar: benign / likely benign; called by mutect2, varscan2
- SCARF1 | c.2069C>T p.T690M | Missense Mutation (SNP) | VAF 284/673 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs536994425; called by muse, varscan2
- SCLY | c.1283G>A p.R428H (on ENST00000651534; = p.R420H on NM_016510.7) | Missense Mutation (SNP) | VAF 461/1058 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258621028, COSV54540122; called by muse, mutect2, varscan2
- SCRN2 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 506/1160 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs143848838; called by muse, mutect2, varscan2
- SDE2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 110/2348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55250209, COSV55251711; called by muse, mutect2
- SDK1 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 254/1158 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs201341557; called by muse, mutect2, varscan2
- SEC16A | c.1689dup p.K564* | Frame Shift Ins (INS) | VAF 156/364 reads (43%) | catalogued as rs1187752611; called by mutect2, varscan2
- SEMA4B | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 267/637 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs766507680, COSV60175472; called by muse, mutect2, varscan2
- SEMA5A | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 498/1475 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs764789764; called by muse, mutect2, varscan2
- SETD1B | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 471/1066 reads (44%) | catalogued as COSV99930412; called by muse, mutect2, varscan2
- SETD1B | c.5543C>T p.A1848V | Missense Mutation (SNP) | VAF 81/741 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs780663276; called by muse, mutect2, varscan2
- SHANK3 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 172/479 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770211391, COSV99437583; called by muse, mutect2, varscan2
- SHOX2 | c.815C>T p.A272V (on ENST00000441443 / NM_006884.3; = p.A296V on NM_003030.4) | Missense Mutation (SNP) | VAF 156/990 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV67463698; called by muse, mutect2, varscan2
- SHQ1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 552/1309 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764950055; called by muse, mutect2, varscan2
- SHROOM3 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 359/467 reads (77%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1314599446; called by muse, mutect2, varscan2
- SIRT6 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 171/403 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs201176270; called by muse, mutect2, varscan2
- SKIV2L | c.3089G>A p.R1030Q | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.886); catalogued as rs545274656; called by muse, mutect2
- SLAMF8 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 72/1141 reads (6%) | catalogued as rs766523263, COSV56988157; called by muse, mutect2
- SLC12A1 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 657/1643 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as CM095066; called by muse, mutect2, varscan2
- SLC17A4 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 691/1644 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs374082636; called by muse, mutect2, varscan2
- SLC22A11 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 472/1088 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs1412431218, COSV57252400; called by muse, varscan2
- SLC25A43 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 698/775 reads (90%) | catalogued as rs201271542, CM134635, COSV54218945; called by muse, mutect2, varscan2
- SLC27A1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 231/801 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1045092614; called by muse, mutect2, varscan2
- SLC35A3 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 675/1685 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1176953471, COSV64515773; called by muse, mutect2, varscan2
- SLC38A2 | c.1180-5dup | Splice Region (INS) | VAF 317/756 reads (42%) | catalogued as rs755947254; called by mutect2, varscan2
- SLC6A19 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 564/986 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs200783817; called by muse, mutect2, varscan2
- SLC9C1 | c.29dup p.S11Qfs*3 | Frame Shift Ins (INS) | VAF 258/968 reads (27%) | catalogued as rs749004401; called by mutect2, varscan2
- SLTM | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 354/911 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1283520688; called by mutect2, varscan2
- SMAP2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 380/992 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1018628232; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 366/906 reads (40%) | catalogued as rs747405143; called by mutect2, varscan2
- SNIP1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 294/581 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs757458483; called by muse, mutect2, varscan2
- SNTA1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 467/1070 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs779370807, COSV54129030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNTB1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 449/1038 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as rs752413892, COSV67324433; called by muse, mutect2, varscan2
- SNX8 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 223/552 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99770894; called by muse, mutect2, varscan2
- SOGA1 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 437/1068 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs748864019; called by muse, mutect2, varscan2
- SOHLH1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 290/742 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215878276; called by muse, mutect2, varscan2
- SOX30 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 395/494 reads (80%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs1490714905; called by muse, mutect2, varscan2
- SOX6 | c.2087G>A p.R696H (on ENST00000528429 / NM_001145819.2; = p.R669H on NM_017508.3) | Missense Mutation (SNP) | VAF 810/1995 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57036569; called by muse, mutect2, varscan2
- SPEN | c.8420G>A p.R2807H | Missense Mutation (SNP) | VAF 328/754 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1032279699, COSV65366718; called by muse, mutect2, varscan2
- SPTBN2 | c.5104G>A p.E1702K | Missense Mutation (SNP) | VAF 326/822 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs781647988, COSV59457261; called by muse, mutect2, varscan2
- SPTBN5 | c.6266G>A p.R2089H | Missense Mutation (SNP) | VAF 584/1374 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs768692793; called by muse, mutect2, varscan2
- SRGAP1 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 128/1383 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1401655826; called by muse, mutect2
- SRGAP3 | c.3287C>T p.S1096L | Missense Mutation (SNP) | VAF 227/567 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs1217900849; called by muse, mutect2, varscan2
- SRPK3 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 585/658 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs139480291; called by muse, mutect2, varscan2
- SSX5 | c.128C>T p.S43L (on ENST00000347757 / NM_175723.1; = p.S84L on NM_021015.4) | Missense Mutation (SNP) | VAF 774/888 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs781880821; called by muse, mutect2, varscan2
- ST6GAL1 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 520/1198 reads (43%) | PolyPhen possibly damaging (0.77); catalogued as COSV99399322; called by muse, varscan2
- STON1-GTF2A1L | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 297/2097 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375824947; called by muse, mutect2, varscan2
- SULT4A1 | c.508+1G>A p.X170_splice | Splice Site (SNP) | VAF 176/668 reads (26%) | catalogued as rs1300942161; called by muse, mutect2, varscan2
- SUN3 | c.876del p.K292Nfs*9 | Frame Shift Del (DEL) | VAF 417/1007 reads (41%) | catalogued as COSV52049484; called by mutect2, varscan2
- SUZ12 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 508/1824 reads (28%) | catalogued as rs372162318, COSV59497708; called by muse, mutect2
- SYNGR4 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 141/738 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.018); catalogued as rs752596742, COSV61225581; called by muse, mutect2, varscan2
- TACC3 | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 465/1263 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs958046998; called by muse, mutect2, varscan2
- TARS2 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 421/978 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1213437290; called by muse, mutect2, varscan2
- TASP1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 292/1918 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as rs950647494, COSV61812971; called by muse, mutect2, varscan2
- TBC1D22B | c.672G>A p.S224= | Splice Region (SNP) | VAF 64/583 reads (11%) | catalogued as rs917165951, COSV65143334; called by muse, mutect2, varscan2
- TBRG4 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 322/844 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1003141735; called by muse, mutect2, varscan2
- TCF23 | c.225C>T p.S75= | Splice Region (SNP) | VAF 235/447 reads (53%) | catalogued as rs777045932, COSV99940428; called by muse, mutect2, varscan2
- TDRD10 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 390/965 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866112987; called by muse, mutect2, varscan2
- TGFB1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 475/1140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1274564517, COSV55726086; called by muse, mutect2, varscan2
- THOP1 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 247/988 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as rs144166691; called by muse, mutect2, varscan2
- TJP1 | c.2798C>T p.S933L | Missense Mutation (SNP) | VAF 491/1224 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.101); catalogued as rs768465018, COSV62041715; called by muse, mutect2, varscan2
- TLE3 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 175/482 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs370686397; called by muse, mutect2, varscan2
- TMEM132C | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 404/995 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs963992961, COSV59422257, COSV59435631; called by muse, mutect2, varscan2
- TMEM147 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 321/780 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1335212423, COSV52869140; called by muse, mutect2, varscan2
- TMEM14B | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 629/1570 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.073); catalogued as rs768149512, COSV65355733; called by muse, mutect2, varscan2
- TMEM231 | c.454G>A p.V152M (on ENST00000258173 / NM_001077418.3; = p.V181M on NM_001077416.2) | Missense Mutation (SNP) | VAF 221/767 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs762041003; called by muse, mutect2, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 231/932 reads (25%) | catalogued as rs747222326; called by mutect2, varscan2
- TMPRSS11D | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 117/1052 reads (11%) | catalogued as rs201111407, COSV52224309; called by muse, mutect2, varscan2
- TNR | c.3347C>T p.T1116M | Missense Mutation (SNP) | VAF 115/1048 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs148101484; called by muse, mutect2, varscan2
- TNXB | c.13469del p.G4490Efs*? (on ENST00000647633; = p.G4243Efs*? on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs1562766298; called by mutect2, varscan2
- TNXB | c.8197C>T p.R2733W (on ENST00000647633; = p.R2486W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 440/1215 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs752650618, COSV64480435; called by muse, mutect2
- TOR3A | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 448/1081 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs117703516; called by muse, mutect2, varscan2
- TREM1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 137/1230 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as rs749632049, COSV55147968; called by muse, mutect2, varscan2
- TRIM8 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 261/332 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); catalogued as rs757863586; called by muse, mutect2, varscan2
- TRPV2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 407/893 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.083); catalogued as rs199855622; called by muse, mutect2, varscan2
- TSC2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 116/674 reads (17%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.993); catalogued as rs375824753; ClinVar: benign / conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTLL3 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 313/749 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755665773; called by muse, mutect2, varscan2
- TULP4 | c.1207dup p.R403Pfs*91 | Frame Shift Ins (INS) | VAF 148/998 reads (15%) | catalogued as rs746002490; called by mutect2, varscan2
- UBAP1L | c.739dup p.A247Gfs*13 | Frame Shift Ins (INS) | VAF 188/460 reads (41%) | catalogued as rs753661357; called by mutect2, varscan2
- UPF1 | c.2267C>T p.P756L (on ENST00000599848 / NM_001297549.2; = p.P745L on NM_002911.4) | Missense Mutation (SNP) | VAF 474/1069 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99439547; called by muse, mutect2, varscan2
- URGCP | c.2053C>T p.R685* (on ENST00000453200 / NM_001077663.3; = p.R676* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 340/735 reads (46%) | catalogued as rs776220574, COSV56251597; called by muse, mutect2, varscan2
- USP31 | c.2441C>T p.S814L | Missense Mutation (SNP) | VAF 52/2056 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1342621748, COSV54853766; called by muse, mutect2
- USP42 | c.3485G>A p.R1162Q | Missense Mutation (SNP) | VAF 86/1587 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1049992287; called by muse, mutect2
- VAC14 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 620/1342 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.116); catalogued as rs1453116826, COSV55752938; called by muse, mutect2, varscan2
- VARS1 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 95/785 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748191897; called by muse, mutect2, varscan2
- VPS13D | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 651/1570 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747960751, COSV62533318; called by muse, mutect2, varscan2
- VPS13D | c.10015G>A p.G3339R | Missense Mutation (SNP) | VAF 152/1115 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV50662429; called by muse, mutect2, varscan2
- VPS28 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 215/775 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782293340, COSV52871549; called by muse, mutect2, varscan2
- VPS52 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 151/1275 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1034587621; called by muse, mutect2, varscan2
- WDFY4 | c.6899G>A p.R2300H | Missense Mutation (SNP) | VAF 155/662 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs537213971, COSV55443362; called by muse, mutect2, varscan2
- WDR91 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 545/1266 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs895332762, COSV60368826; called by muse, mutect2, varscan2
- WFDC8 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 668/1598 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.744); catalogued as rs553616555; called by muse, mutect2, varscan2
- WNT10A | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 308/740 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs372756514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWC1 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 365/471 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs549137219, COSV99516034; called by muse, mutect2, varscan2
- ZBTB24 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 810/1985 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57783202; called by muse, mutect2, varscan2
- ZBTB4 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 174/1279 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs745793162, COSV60983454; called by muse, mutect2, varscan2
- ZBTB40 | c.3257C>T p.T1086M | Missense Mutation (SNP) | VAF 518/1228 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs533226667, COSV65145402; called by muse, mutect2, varscan2
- ZFR | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 597/1403 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367873889; called by muse, mutect2, varscan2
- ZFYVE27 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 424/530 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759151979, COSV61747444; called by muse, mutect2, varscan2
- ZNF175 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 83/697 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376681504; called by muse, mutect2, varscan2
- ZNF319 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 69/580 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs765801463, COSV54623085; called by muse, mutect2, varscan2
- ZNF454 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 54/1152 reads (5%) | catalogued as rs1217144684, COSV100194890; called by muse, mutect2
- ZNF497 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 211/476 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs541600828, COSV54053583; called by muse, mutect2, varscan2
- ZNF541 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 209/453 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs370590971; called by muse, mutect2, varscan2
- ZNF596 | c.12G>A p.P4= | Splice Region (SNP) | VAF 388/944 reads (41%) | catalogued as rs200449135; called by muse, mutect2, varscan2
- ZNF628 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 199/540 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs772642387; called by muse, mutect2, varscan2
- ZNF737 | c.513dup p.P172Tfs*12 | Frame Shift Ins (INS) | VAF 86/198 reads (43%) | catalogued as rs782545661; called by mutect2, varscan2
- ZNF793 | c.862del p.C288Vfs*113 | Frame Shift Del (DEL) | VAF 110/800 reads (14%) | catalogued as rs761241629, COSV101495729; called by mutect2, varscan2
- ZNF813 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs374486164; called by muse, mutect2, varscan2
- ZNF843 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 153/520 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1363727345, COSV59847629; called by muse, mutect2, varscan2
- ZSWIM4 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 243/574 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs762511371, COSV54325528; called by muse, mutect2, varscan2
- AGAP2 | c.2947G>A p.V983I (on ENST00000547588 / NM_001122772.2; = p.V627I on NM_014770.4) | Missense Mutation (SNP) | VAF 451/1043 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- AKAP5 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 610/1500 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD13A | c.346dup p.I116Nfs*24 | Frame Shift Ins (INS) | VAF 190/1383 reads (14%) | called by mutect2, varscan2
- ANKRD28 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 789/2088 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ARHGAP25 | c.889C>T p.H297Y (on ENST00000409202 / NM_001007231.3; = p.H289Y on NM_014882.3) | Missense Mutation (SNP) | VAF 740/1713 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGAP44 | c.1708G>C p.A570P | Missense Mutation (SNP) | VAF 103/823 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1A2 | c.1939A>T p.I647F | Missense Mutation (SNP) | VAF 123/885 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ATRX | c.2093dup p.D699Gfs*2 | Frame Shift Ins (INS) | VAF 582/691 reads (84%) | called by mutect2, varscan2
- ATXN7L2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 192/800 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- BAIAP3 | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- BCL11A | c.971C>T p.P324L (on ENST00000335712 / NM_001365609.1; = p.P358L on NM_018014.4) | Missense Mutation (SNP) | VAF 254/544 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by mutect2, varscan2
- BORCS6 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 142/311 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPTF | c.3204G>A p.M1068I | Missense Mutation (SNP) | VAF 77/1729 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2
- C3orf38 | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 723/1689 reads (43%) | called by muse, mutect2, varscan2
- CABIN1 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 256/596 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CACNA1A | c.4261C>T p.R1421* | Nonsense Mutation (SNP) | VAF 365/921 reads (40%) | called by muse, mutect2, varscan2
- CACNA1C | c.4069T>C p.F1357L | Missense Mutation (SNP) | VAF 119/712 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CAMSAP3 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 170/387 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CARD8 | c.11del p.K4Rfs*25 (on ENST00000651546 / NM_001184900.3; = p.K4Rfs*87 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 87/808 reads (11%) | called by mutect2, varscan2
- CCDC137 | c.495dup p.A166Sfs*9 | Frame Shift Ins (INS) | VAF 98/661 reads (15%) | called by mutect2, varscan2
- CCDC171 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 322/1796 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCR7 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 136/1638 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CD164L2 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 282/745 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP126 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 337/1584 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CHD4 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 205/1054 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CHD9 | c.4854dup p.H1619Tfs*7 | Frame Shift Ins (INS) | VAF 163/1154 reads (14%) | called by mutect2, varscan2
- CORO7 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 265/657 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CRAT | c.1867del p.R623Gfs*47 | Frame Shift Del (DEL) | VAF 72/544 reads (13%) | called by mutect2, varscan2
- CYHR1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 369/874 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CYP19A1 | c.1457del p.N486Tfs*5 | Frame Shift Del (DEL) | VAF 676/1552 reads (44%) | called by mutect2, varscan2
- CYTH3 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 153/1327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX21 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 179/630 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- DDX24 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 364/855 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND4C | c.3877del p.S1293Vfs*3 (on ENST00000434457 / NM_001330640.2; = p.S1244Vfs*3 on NM_017925.7) | Frame Shift Del (DEL) | VAF 640/817 reads (78%) | called by mutect2, varscan2
- DOCK11 | c.848del p.K283Rfs*4 | Frame Shift Del (DEL) | VAF 199/544 reads (37%) | called by mutect2, varscan2
- DYNC2H1 | c.3552_3555del p.S1185Rfs*8 | Frame Shift Del (DEL) | VAF 572/1475 reads (39%) | called by mutect2, varscan2
- FAM135A | c.2996dup p.N999Kfs*2 (on ENST00000370479 / NM_001351599.1; = p.N786Kfs*2 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 270/1020 reads (26%) | called by mutect2, varscan2
- FCGBP | c.10562C>T p.A3521V | Missense Mutation (SNP) | VAF 285/691 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- GABRG3 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 67/1577 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GNAS | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 105/854 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GPX4 | c.458dup p.K154Qfs*? | Frame Shift Ins (INS) | VAF 310/682 reads (45%) | called by mutect2, varscan2
- HAVCR1 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 454/566 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HCN2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 38/720 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- HERC1 | c.10508G>A p.G3503D | Missense Mutation (SNP) | VAF 217/2012 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HSCB | c.403del p.L135* | Frame Shift Del (DEL) | VAF 372/868 reads (43%) | called by mutect2, varscan2
- KANSL1L | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 41/1766 reads (2%) | SIFT deleterious (0.05); PolyPhen benign (0.435); called by muse, mutect2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 369/932 reads (40%) | called by mutect2, varscan2
- KLF8 | c.645A>G p.S215= | Splice Region (SNP) | VAF 337/371 reads (91%) | called by muse, mutect2, varscan2
- KMT2D | c.1061del p.G354Efs*48 | Frame Shift Del (DEL) | VAF 126/1020 reads (12%) | called by mutect2, varscan2
- LARGE2 | c.883-5C>T | Splice Region (SNP) | VAF 48/479 reads (10%) | called by muse, mutect2
- LLGL1 | c.2647A>G p.N883D | Missense Mutation (SNP) | VAF 243/548 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- LRRD1 | c.724del p.Y242Ifs*12 | Frame Shift Del (DEL) | VAF 472/1166 reads (40%) | called by mutect2, varscan2
- LYL1 | c.119del p.P40Rfs*23 | Frame Shift Del (DEL) | VAF 241/474 reads (51%) | called by mutect2, varscan2
- MAP10 | c.1987dup p.R663Kfs*5 | Frame Shift Ins (INS) | VAF 634/1532 reads (41%) | called by mutect2, varscan2
- MAST2 | c.1909A>G p.K637E | Missense Mutation (SNP) | VAF 137/1056 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MED24 | c.2109del p.K704Sfs*8 | Frame Shift Del (DEL) | VAF 92/520 reads (18%) | called by mutect2, varscan2
- MEX3A | c.200del p.G67Afs*60 | Frame Shift Del (DEL) | VAF 52/124 reads (42%) | called by mutect2, varscan2
- MFHAS1 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 156/1053 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MTF1 | c.991-1G>T p.X331_splice | Splice Site (SNP) | VAF 108/1162 reads (9%) | called by muse, mutect2
- MUC19 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 202/1706 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC3A | c.9197del p.G3066Afs*12 | Frame Shift Del (DEL) | VAF 208/1031 reads (20%) | called by mutect2, varscan2
- MYCT1 | c.86del p.F29Sfs*28 | Frame Shift Del (DEL) | VAF 804/2037 reads (39%) | called by mutect2, varscan2
- MYMX | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 35/1390 reads (3%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MYO15B | c.3876G>C p.K1292N | Missense Mutation (SNP) | VAF 339/851 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYOM1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 492/592 reads (83%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAA25 | c.2796G>A p.P932= | Splice Region (SNP) | VAF 105/1017 reads (10%) | called by muse, mutect2, varscan2
- NCOA6 | c.3518T>C p.L1173P | Missense Mutation (SNP) | VAF 138/1268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NNT | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 178/1117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- NOD1 | c.2370-6_2370-5dup | Splice Region (INS) | VAF 413/1087 reads (38%) | called by mutect2, varscan2
- OBSCN | c.7462C>A p.L2488M | Missense Mutation (SNP) | VAF 287/726 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ODF2L | c.1361_1363del p.M454del (on ENST00000317336; = p.M425del on NM_020729.3) | In Frame Del (DEL) | VAF 99/881 reads (11%) | called by mutect2, varscan2
- OPRL1 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 242/513 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR5B17 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 50/1407 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.458); called by muse, mutect2
- OSBPL8 | c.551dup p.N184Kfs*14 | Frame Shift Ins (INS) | VAF 749/1637 reads (46%) | called by mutect2, varscan2
- OTUD4 | c.1303C>T p.R435* (on ENST00000447906 / NM_001366057.1; = p.R370* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 628/810 reads (78%) | called by muse, varscan2
- PCDHA9 | c.1776del p.K593Rfs*59 | Frame Shift Del (DEL) | VAF 308/382 reads (81%) | called by mutect2, varscan2
- PDGFRA | c.1123T>C p.Y375H | Missense Mutation (SNP) | VAF 420/8279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- PDXDC1 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 426/2152 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PI4KA | c.3748C>T p.R1250W | Missense Mutation (SNP) | VAF 36/1238 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- PITPNC1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 54/1666 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- PNISR | c.798dup p.E267Rfs*9 | Frame Shift Ins (INS) | VAF 192/1744 reads (11%) | called by mutect2, varscan2
- PPL | c.3401C>T p.T1134I | Missense Mutation (SNP) | VAF 301/768 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PPP1R2C | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 749/858 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP4R4 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 617/1443 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 173/683 reads (25%) | called by mutect2, varscan2
- PTPRQ | c.6544dup p.I2182Nfs*2 (on ENST00000616559; = p.I2149Nfs*2 on NM_001145026.2) | Frame Shift Ins (INS) | VAF 490/1190 reads (41%) | called by mutect2, varscan2
- RAMAC | c.-9-3_-9-2del | Splice Region (DEL) | VAF 302/698 reads (43%) | called by mutect2, varscan2
- RBBP6 | c.4394_4395del p.K1465Rfs*6 | Frame Shift Del (DEL) | VAF 756/1854 reads (41%) | called by mutect2, varscan2
- RBM14 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 375/737 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- RBM14 | c.1883C>A p.P628Q | Missense Mutation (SNP) | VAF 340/1195 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- RNF146 | c.838G>A p.A280T (on ENST00000368314 / NM_001242850.2; = p.A279T on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 679/1631 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPS6KB1 | c.1524dup p.Q509Tfs*24 | Frame Shift Ins (INS) | VAF 595/1434 reads (41%) | called by mutect2, varscan2
- RSPH14 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 71/666 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTF1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 544/1318 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SCGB2A2 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 556/1282 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- SERPINA5 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 163/386 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETD2 | c.1963_1964del p.L655Ifs*2 | Frame Shift Del (DEL) | VAF 474/1169 reads (41%) | called by mutect2, varscan2
- SETX | c.1784_1785del p.I595Kfs*8 | Frame Shift Del (DEL) | VAF 159/1207 reads (13%) | called by mutect2, varscan2
- SHROOM4 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 188/349 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC22A13 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 428/972 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SLC4A8 | c.2725G>A p.G909R | Missense Mutation (SNP) | VAF 153/1089 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A11 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 682/887 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLFN14 | c.1707C>A p.N569K | Missense Mutation (SNP) | VAF 617/1514 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMC4 | c.2367del p.A790Qfs*15 | Frame Shift Del (DEL) | VAF 846/1998 reads (42%) | called by mutect2, varscan2
- SMO | c.1357+8G>A | Splice Region (SNP) | VAF 28/693 reads (4%) | called by muse, mutect2
- SPANXN2 | c.464A>G p.D155G | Missense Mutation (SNP) | VAF 102/1648 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.039); called by muse, mutect2
- SPEF2 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 714/1582 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SSR3 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 581/1417 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- STRN3 | c.78del p.N27Tfs*84 | Frame Shift Del (DEL) | VAF 126/536 reads (24%) | called by mutect2, varscan2
- SULT2B1 | c.317C>A p.T106N (on ENST00000201586 / NM_177973.2; = p.T91N on NM_004605.2) | Missense Mutation (SNP) | VAF 215/483 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SYN1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 773/883 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R16 | c.850A>G p.K284E | Missense Mutation (SNP) | VAF 686/1649 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TEX2 | c.2805-8_2805-7dup | Splice Region (INS) | VAF 94/354 reads (27%) | called by mutect2, varscan2
- TMEM119 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 135/945 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TMEM151A | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TNFRSF13B | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 451/1111 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TNRC6B | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TPGS1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- TREML4 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 296/659 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM31 | c.876del p.K292Nfs*21 | Frame Shift Del (DEL) | VAF 262/903 reads (29%) | called by mutect2, varscan2
- TRIML2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 395/487 reads (81%) | SIFT tolerated (0.08); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- TSPAN4 | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 36/906 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC17 | c.3309dup p.A1104Sfs*6 | Frame Shift Ins (INS) | VAF 362/748 reads (48%) | called by mutect2, varscan2
- TTLL11 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 159/358 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- TTLL7 | c.1292_1295del p.K431Rfs*42 | Frame Shift Del (DEL) | VAF 664/1684 reads (39%) | called by mutect2, varscan2
- UBAP1 | c.767del p.P256Lfs*5 | Frame Shift Del (DEL) | VAF 126/1006 reads (13%) | called by mutect2, varscan2
- UTRN | c.2216_2219del p.R739Kfs*9 | Frame Shift Del (DEL) | VAF 622/1361 reads (46%) | called by mutect2, varscan2
- VCX3A | c.174del p.M59Wfs*4 | Frame Shift Del (DEL) | VAF 92/190 reads (48%) | called by mutect2, varscan2
- VCX3B | c.174del p.M59Wfs*4 | Frame Shift Del (DEL) | VAF 18/21 reads (86%) | called by mutect2, varscan2
- WNT3 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 281/704 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZBTB25 | c.415del p.T139Qfs*75 | Frame Shift Del (DEL) | VAF 108/926 reads (12%) | called by mutect2, varscan2
- ZNF358 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 306/747 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ZNF408 | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 46/640 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZNF775 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 232/478 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AATK | c.1800G>A p.A600= (on ENST00000326724 / NM_001080395.3; = p.A497= on NM_004920.2) | Silent (SNP) | VAF 88/794 reads (11%) | called by muse, varscan2
- ABCA7 | c.4080G>A p.P1360= | Silent (SNP) | VAF 214/542 reads (39%) | catalogued as rs1461237405; called by muse, mutect2
- ABCA8 | c.3339G>A p.A1113= | Silent (SNP) | VAF 132/2164 reads (6%) | catalogued as rs375561539; called by muse, mutect2
- AC092143.1 | c.2118C>T p.R706= | Silent (SNP) | VAF 126/1142 reads (11%) | catalogued as rs777734748, COSV59247610; called by muse, mutect2, varscan2
- ADPRHL1 | c.1191G>A p.T397= | Silent (SNP) | VAF 266/464 reads (57%) | catalogued as rs576280147; called by muse, mutect2, varscan2
- AKAP8 | c.1476G>A p.P492= | Silent (SNP) | VAF 70/1178 reads (6%) | catalogued as rs368445659; called by muse, mutect2
- ANKRD61 | c.624C>T p.A208= | Silent (SNP) | VAF 243/594 reads (41%) | catalogued as rs1322616929, COSV52237937; called by muse, mutect2, varscan2
- APC2 | c.6459C>T p.D2153= | Silent (SNP) | VAF 53/481 reads (11%) | catalogued as rs1296307578; called by muse, mutect2, varscan2
- ARFGEF2 | c.849C>T p.D283= | Silent (SNP) | VAF 438/1158 reads (38%) | catalogued as rs749624687; called by muse, mutect2, varscan2
- ARRDC1 | c.1068G>A p.P356= | Silent (SNP) | VAF 239/557 reads (43%) | catalogued as rs777406745; called by muse, mutect2, varscan2
- ATP1A2 | c.1083G>A p.A361= | Silent (SNP) | VAF 501/1235 reads (41%) | catalogued as rs778171140, COSV63405069; called by muse, varscan2
- ATP2B2 | c.2532C>T p.D844= (on ENST00000352432; = p.D810= on NM_001683.5) | Silent (SNP) | VAF 308/1289 reads (24%) | catalogued as rs199729964; called by muse, mutect2, varscan2
- ATP4B | c.699C>T p.Y233= | Silent (SNP) | VAF 165/907 reads (18%) | catalogued as rs780634880; called by muse, mutect2, varscan2
- ATP6AP1 | c.789C>T p.T263= | Silent (SNP) | VAF 247/457 reads (54%) | catalogued as rs374472574; called by muse, mutect2, varscan2
- B4GALT4 | c.474C>T p.Y158= | Silent (SNP) | VAF 151/1074 reads (14%) | catalogued as rs1043118470; called by muse, mutect2, varscan2
- BIN1 | c.162G>A p.Q54= | Silent (SNP) | VAF 293/740 reads (40%) | called by muse, mutect2, varscan2
- BSND | c.288G>A p.P96= | Silent (SNP) | VAF 684/1601 reads (43%) | catalogued as rs752911029, COSV64870626; called by muse, mutect2, varscan2
- BVES | c.327G>A p.S109= | Silent (SNP) | VAF 419/1738 reads (24%) | catalogued as rs139347341; called by muse, mutect2, varscan2
- CACNA1C | c.1674G>A p.T558= | Silent (SNP) | VAF 436/797 reads (55%) | catalogued as rs781180544, COSV59713120; ClinVar: benign; called by muse, mutect2, varscan2
- CACNA1E | c.6708C>T p.H2236= (on ENST00000367573 / NM_001205293.3; = p.H2193= on NM_000721.4) | Silent (SNP) | VAF 402/952 reads (42%) | catalogued as rs746438533, COSV62415033; called by muse, mutect2, varscan2
- CAMSAP3 | c.3582G>A p.T1194= | Silent (SNP) | VAF 199/435 reads (46%) | catalogued as rs879187204; called by muse, mutect2, varscan2
- CASKIN2 | c.2010C>T p.S670= | Silent (SNP) | VAF 190/416 reads (46%) | catalogued as rs566377574; called by muse, mutect2, varscan2
- CCDC105 | c.888G>A p.A296= | Silent (SNP) | VAF 271/636 reads (43%) | catalogued as rs139591424; called by muse, mutect2, varscan2
- CCDC144A | c.2307C>T p.N769= | Silent (SNP) | VAF 120/1062 reads (11%) | catalogued as rs760389448; called by muse, mutect2, varscan2
- CCER1 | c.660G>A p.T220= | Silent (SNP) | VAF 462/1098 reads (42%) | catalogued as rs374806312, COSV62646449; called by muse, mutect2, varscan2
- CCER1 | c.108G>A p.S36= | Silent (SNP) | VAF 312/1267 reads (25%) | catalogued as rs370822454, COSV62648740; called by muse, mutect2, varscan2
- CCR8 | c.117T>G p.A39= | Silent (SNP) | VAF 591/1238 reads (48%) | called by muse, mutect2, varscan2
- CDH7 | c.57G>T p.L19= | Silent (SNP) | VAF 351/1310 reads (27%) | called by muse, mutect2, varscan2
- CDK19 | c.1338C>T p.G446= | Silent (SNP) | VAF 627/1533 reads (41%) | catalogued as rs748955098, COSV60450151; called by muse, mutect2, varscan2
- CHSY1 | c.2344C>T p.L782= | Silent (SNP) | VAF 493/1138 reads (43%) | catalogued as rs758767075; called by muse, mutect2, varscan2
- CILP2 | c.1500C>T p.I500= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as rs1386748289; called by muse, mutect2, varscan2
- CNST | c.2109C>T p.N703= | Silent (SNP) | VAF 318/1262 reads (25%) | called by muse, mutect2, varscan2
- COL6A1 | c.1137C>T p.D379= | Silent (SNP) | VAF 59/1018 reads (6%) | catalogued as rs1009125960, COSV62612174, COSV62613991; called by muse, mutect2
- COL6A5 | c.4881G>A p.G1627= | Silent (SNP) | VAF 132/1258 reads (10%) | called by muse, mutect2, varscan2
- COL9A1 | c.813G>A p.P271= | Silent (SNP) | VAF 328/820 reads (40%) | catalogued as rs577301262, COSV57886962; called by muse, mutect2, varscan2
- CPSF1 | c.4095G>A p.A1365= | Silent (SNP) | VAF 254/614 reads (41%) | catalogued as rs1554862312; called by muse, mutect2, varscan2
- CRTC3 | c.1008G>A p.T336= | Silent (SNP) | VAF 79/678 reads (12%) | catalogued as rs145349033; called by muse, mutect2, varscan2
- CSMD3 | c.9135A>G p.Q3045= (on ENST00000297405 / NM_001363185.1; = p.Q2876= on NM_052900.3) | Silent (SNP) | VAF 154/1469 reads (10%) | called by muse, mutect2, varscan2
- CSPG4 | c.4149C>T p.S1383= | Silent (SNP) | VAF 58/357 reads (16%) | catalogued as rs778574722; called by muse, mutect2, varscan2
- CYTH1 | c.1032C>T p.D344= | Silent (SNP) | VAF 558/1366 reads (41%) | catalogued as rs199612995, COSV63122864; called by muse, mutect2, varscan2
- DAPK1 | c.1215C>T p.I405= | Silent (SNP) | VAF 557/1415 reads (39%) | catalogued as rs773237491; called by muse, mutect2, varscan2
- DEAF1 | c.597C>T p.Y199= | Silent (SNP) | VAF 159/1203 reads (13%) | catalogued as rs766189868; called by muse, mutect2, varscan2
- DENND4B | c.1683G>A p.R561= | Silent (SNP) | VAF 82/893 reads (9%) | called by muse, mutect2
- DICER1 | c.366G>C p.G122= | Silent (SNP) | VAF 193/1718 reads (11%) | called by muse, mutect2, varscan2
- DLC1 | c.2301G>A p.A767= (on ENST00000276297 / NM_001348081.2; = p.A330= on NM_006094.5) | Silent (SNP) | VAF 450/1018 reads (44%) | catalogued as rs376046492; called by muse, mutect2, varscan2
- E2F7 | c.1869G>A p.S623= | Silent (SNP) | VAF 92/802 reads (11%) | catalogued as rs367601021; called by muse, mutect2, varscan2
- ERRFI1 | c.960G>A p.P320= | Silent (SNP) | VAF 411/974 reads (42%) | catalogued as rs371415623; called by muse, mutect2, varscan2
- ETV7 | c.255C>T p.R85= | Silent (SNP) | VAF 224/743 reads (30%) | catalogued as rs141591162; called by muse, mutect2, varscan2
- F2RL3 | c.939C>T p.S313= | Silent (SNP) | VAF 63/448 reads (14%) | catalogued as rs775640062, COSV50186713; called by muse, mutect2, varscan2
- FAT3 | c.12474C>T p.I4158= | Silent (SNP) | VAF 488/1283 reads (38%) | catalogued as rs1478000445, COSV53144510; called by muse, mutect2, varscan2
- FBLN2 | c.153G>A p.P51= | Silent (SNP) | VAF 225/457 reads (49%) | catalogued as rs757605729; called by muse, mutect2, varscan2
- FHOD1 | c.714G>A p.P238= | Silent (SNP) | VAF 147/1332 reads (11%) | catalogued as rs757563031; called by muse, mutect2, varscan2
- FLNA | c.6297C>T p.D2099= (on ENST00000369850 / NM_001110556.2; = p.D2091= on NM_001456.3) | Silent (SNP) | VAF 255/456 reads (56%) | catalogued as rs377571943, COSV61042792; called by muse, mutect2, varscan2
- FN3KRP | c.375G>A p.A125= | Silent (SNP) | VAF 209/511 reads (41%) | catalogued as rs373904593; called by muse, mutect2, varscan2
- FOXF2 | c.144C>G p.S48= | Silent (SNP) | VAF 183/430 reads (43%) | catalogued as rs748534796; called by muse, mutect2, varscan2
- FOXO6 | c.1020G>A p.P340= | Silent (SNP) | VAF 179/338 reads (53%) | called by muse, mutect2, varscan2
- FTMT | c.444G>A p.P148= | Silent (SNP) | VAF 517/629 reads (82%) | catalogued as rs143840903; called by muse, mutect2, varscan2
- GALNT15 | c.1161G>A p.S387= | Silent (SNP) | VAF 807/1843 reads (44%) | catalogued as rs756866951, COSV60218816; called by muse, mutect2, varscan2
- GBA | c.1452C>T p.D484= | Silent (SNP) | VAF 567/2012 reads (28%) | catalogued as rs546737014, CD972232; called by muse, mutect2, varscan2
- GEMIN6 | c.366C>T p.D122= | Silent (SNP) | VAF 391/878 reads (45%) | catalogued as rs200834111; called by muse, mutect2, varscan2
- GET1 | c.390C>T p.V130= | Silent (SNP) | VAF 96/1868 reads (5%) | catalogued as rs11548341; called by muse, mutect2
- GPR45 | c.201G>A p.S67= | Silent (SNP) | VAF 190/467 reads (41%) | catalogued as rs779954345, COSV51522604; called by muse, mutect2, varscan2
- GRHPR | c.159C>T p.H53= | Silent (SNP) | VAF 246/638 reads (39%) | catalogued as rs781026957; called by muse, mutect2, varscan2
- HCAR3 | c.243G>A p.P81= | Silent (SNP) | VAF 475/1175 reads (40%) | catalogued as rs3825151; called by muse, mutect2, varscan2
- HDAC9 | c.504C>T p.S168= | Silent (SNP) | VAF 818/1911 reads (43%) | catalogued as rs757411806, COSV67770640, COSV67772958; called by muse, varscan2
- HEPH | c.3450C>T p.S1150= (on ENST00000343002; = p.S883= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/754 reads (5%) | called by muse, mutect2
- HERC2 | c.13485C>T p.N4495= | Silent (SNP) | VAF 283/680 reads (42%) | catalogued as rs201520077, COSV55328181; called by muse, mutect2, varscan2
- HMCN2 | c.13521C>T p.L4507= | Silent (SNP) | VAF 305/731 reads (42%) | catalogued as rs1335215511; called by muse, mutect2, varscan2
- HMCN2 | c.15024C>A p.P5008= | Silent (SNP) | VAF 77/213 reads (36%) | called by muse, mutect2, varscan2
- HYAL2 | c.1101G>T p.R367= | Silent (SNP) | VAF 364/767 reads (47%) | called by muse, mutect2, varscan2
- IFIT1 | c.534C>T p.S178= | Silent (SNP) | VAF 456/580 reads (79%) | catalogued as rs554970189, COSV100878732; called by muse, mutect2, varscan2
- IGSF9 | c.1863G>A p.P621= (on ENST00000368094 / NM_001135050.2; = p.P605= on NM_020789.4) | Silent (SNP) | VAF 378/860 reads (44%) | catalogued as rs781604563, COSV63641396; called by muse, mutect2, varscan2
- IL20RA | c.1512C>T p.C504= | Silent (SNP) | VAF 248/569 reads (44%) | catalogued as rs1562226273; called by muse, mutect2, varscan2
- IL34 | c.114G>A p.T38= | Silent (SNP) | VAF 394/935 reads (42%) | catalogued as rs554531579, COSV55380037; called by muse, mutect2, varscan2
- JMJD1C | c.2298C>T p.A766= | Silent (SNP) | VAF 149/647 reads (23%) | catalogued as rs569430257; called by muse, mutect2, varscan2
- JPH2 | c.1674G>A p.P558= | Silent (SNP) | VAF 144/282 reads (51%) | catalogued as rs779915700; called by muse, mutect2, varscan2
- JPH3 | c.1644C>T p.R548= | Silent (SNP) | VAF 137/303 reads (45%) | catalogued as COSV52469418; called by muse, mutect2, varscan2
- KIF19 | c.960C>T p.I320= | Silent (SNP) | VAF 244/620 reads (39%) | catalogued as rs766695819, COSV63429010; called by muse, mutect2, varscan2
- KLHDC7A | c.1440C>T p.R480= | Silent (SNP) | VAF 218/445 reads (49%) | catalogued as rs148313941; called by muse, mutect2, varscan2
- KLHL22 | c.945C>T p.S315= | Silent (SNP) | VAF 206/433 reads (48%) | catalogued as rs749682717, COSV61022424; called by muse, mutect2, varscan2
- KLRG1 | c.342G>A p.T114= | Silent (SNP) | VAF 426/1426 reads (30%) | catalogued as rs763111871, COSV56945022; called by muse, mutect2, varscan2
- LHX2 | c.876C>T p.D292= | Silent (SNP) | VAF 548/1385 reads (40%) | catalogued as rs767627020, COSV65318969; called by muse, mutect2, varscan2
- LOXHD1 | c.4920C>T p.D1640= | Silent (SNP) | VAF 543/1399 reads (39%) | catalogued as rs373551323; called by muse, mutect2, varscan2
- LTN1 | c.4488G>A p.R1496= | Silent (SNP) | VAF 146/1520 reads (10%) | called by muse, mutect2
- MCF2L | c.3354C>T p.S1118= (on ENST00000375608; = p.S1086= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 198/315 reads (63%) | catalogued as rs573145172; called by muse, mutect2, varscan2
- MCRIP2 | c.237G>A p.T79= | Silent (SNP) | VAF 54/535 reads (10%) | catalogued as rs143823191; called by muse, mutect2, varscan2
- MN1 | c.2781G>A p.T927= | Silent (SNP) | VAF 380/867 reads (44%) | catalogued as rs770298219; called by muse, mutect2, varscan2
- MN1 | c.411C>T p.G137= | Silent (SNP) | VAF 103/321 reads (32%) | catalogued as rs1346649836; called by muse, mutect2, varscan2
- MRPL38 | c.852C>T p.D284= | Silent (SNP) | VAF 80/1115 reads (7%) | catalogued as rs777876516; called by muse, mutect2
- MUC19 | c.495C>T p.S165= | Silent (SNP) | VAF 322/835 reads (39%) | catalogued as rs1157315049; called by muse, varscan2
- MUC5AC | c.1680G>A p.A560= | Silent (SNP) | VAF 253/556 reads (46%) | catalogued as rs758333675, COSV62253618; called by muse, mutect2, varscan2
- MVP | c.1413C>T p.Y471= | Silent (SNP) | VAF 325/822 reads (40%) | catalogued as rs200341839; called by muse, mutect2, varscan2
- MXRA5 | c.6183G>A p.P2061= | Silent (SNP) | VAF 291/342 reads (85%) | catalogued as rs746083731; called by muse, mutect2, varscan2
- MYO10 | c.915C>A p.S305= | Silent (SNP) | VAF 280/1181 reads (24%) | called by muse, varscan2
- N4BP2L2 | c.2103C>T p.S701= (on ENST00000674422; = p.S272= on NM_033111.4) | Silent (SNP) | VAF 77/1188 reads (6%) | catalogued as rs569069138; called by muse, mutect2
- NEU4 | c.150C>T p.H50= (on ENST00000391969 / NM_001167602.3; = p.H62= on NM_080741.4) | Silent (SNP) | VAF 224/614 reads (36%) | catalogued as rs375575471; called by muse, mutect2, varscan2
- NFXL1 | c.489T>C p.C163= | Silent (SNP) | VAF 527/3122 reads (17%) | called by muse, mutect2, varscan2
- NOTCH3 | c.6627G>A p.P2209= | Silent (SNP) | VAF 259/710 reads (36%) | catalogued as rs760880486; called by muse, mutect2, varscan2
- NOTCH3 | c.2637C>T p.F879= | Silent (SNP) | VAF 318/866 reads (37%) | catalogued as COSV54642269; called by muse, mutect2, varscan2
- NPAS3 | c.2112C>T p.G704= (on ENST00000356141 / NM_001164749.2; = p.G672= on NM_022123.3) | Silent (SNP) | VAF 217/450 reads (48%) | catalogued as rs1033310782; called by muse, mutect2, varscan2
- NR2F2 | c.858C>T p.V286= | Silent (SNP) | VAF 72/662 reads (11%) | catalogued as rs1475960379; called by muse, mutect2, varscan2
- NUP93 | c.192C>T p.L64= | Silent (SNP) | VAF 429/1065 reads (40%) | catalogued as rs750501091; called by muse, mutect2, varscan2
- OPLAH | c.2976C>T p.D992= | Silent (SNP) | VAF 304/714 reads (43%) | called by muse, mutect2, varscan2
- PAK4 | c.1428C>T p.V476= | Silent (SNP) | VAF 223/565 reads (39%) | catalogued as rs201757969; called by muse, mutect2, varscan2
- PCDHB15 | c.606C>T p.R202= | Silent (SNP) | VAF 151/581 reads (26%) | catalogued as rs782024704; called by muse, mutect2, varscan2
- PCDHGA9 | c.2166G>A p.S722= | Silent (SNP) | VAF 304/625 reads (49%) | catalogued as rs368800698; called by muse, mutect2, varscan2
- PCK1 | c.474C>T p.I158= | Silent (SNP) | VAF 122/1173 reads (10%) | catalogued as rs764002893, COSV60129492; called by muse, mutect2, varscan2
- PERM1 | c.582G>A p.G194= | Silent (SNP) | VAF 161/375 reads (43%) | called by muse, mutect2, varscan2
- PGBD5 | c.915C>T p.T305= (on ENST00000525115; = p.T374= on NM_001258311.2) | Silent (SNP) | VAF 440/1076 reads (41%) | catalogued as rs138865438; called by muse, mutect2, varscan2
- PHYHIP | c.834C>T p.H278= | Silent (SNP) | VAF 38/381 reads (10%) | catalogued as rs763047915, COSV58688257; called by muse, mutect2
- PILRB | c.231C>T p.H77= | Silent (SNP) | VAF 84/830 reads (10%) | catalogued as rs1161169621, COSV60332976; called by muse, mutect2, varscan2
- PLXNA4 | c.4113G>A p.T1371= | Silent (SNP) | VAF 104/1373 reads (8%) | catalogued as rs756256466, COSV100322749; called by muse, mutect2
- POMGNT1 | c.300C>T p.D100= | Silent (SNP) | VAF 91/694 reads (13%) | catalogued as rs748654101, COSV64340578; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKAG3 | c.387C>T p.S129= | Silent (SNP) | VAF 79/691 reads (11%) | catalogued as COSV52101493; called by muse, mutect2, varscan2
- PTGDR2 | c.768G>A p.A256= | Silent (SNP) | VAF 43/410 reads (10%) | catalogued as rs780405518; called by muse, mutect2, varscan2
- PTX4 | c.201C>T p.N67= (on ENST00000447419 / NM_001328608.2; = p.N62= on NM_001013658.1) | Silent (SNP) | VAF 229/955 reads (24%) | catalogued as rs763073016, COSV53515891; called by muse, mutect2, varscan2
- RASSF4 | c.657C>T p.F219= | Silent (SNP) | VAF 351/458 reads (77%) | catalogued as rs192302639; called by muse, mutect2, varscan2
- RBFOX1 | c.1056C>T p.Y352= | Silent (SNP) | VAF 261/1118 reads (23%) | catalogued as rs372365163; called by muse, mutect2, varscan2
- RBM15B | c.2142C>T p.Y714= | Silent (SNP) | VAF 291/726 reads (40%) | catalogued as rs782418158; called by muse, mutect2, varscan2
- RECQL5 | c.2565G>A p.R855= | Silent (SNP) | VAF 366/904 reads (40%) | catalogued as rs1451895854; called by muse, mutect2, varscan2
- RFTN2 | c.1104C>T p.F368= | Silent (SNP) | VAF 147/1445 reads (10%) | catalogued as rs766286621, COSV54385658; called by muse, mutect2, varscan2
- RND2 | c.642C>T p.G214= | Silent (SNP) | VAF 68/988 reads (7%) | catalogued as rs759647649; called by muse, mutect2
- ROR2 | c.444C>T p.G148= | Silent (SNP) | VAF 399/937 reads (43%) | catalogued as rs771472565; called by muse, mutect2, varscan2
- ROS1 | c.6306C>T p.D2102= | Silent (SNP) | VAF 612/1493 reads (41%) | called by muse, mutect2, varscan2
- SEC14L1 | c.615C>T p.A205= | Silent (SNP) | VAF 98/1008 reads (10%) | catalogued as rs574665462; called by muse, mutect2, varscan2
- SIN3A | c.813G>A p.P271= | Silent (SNP) | VAF 533/1254 reads (43%) | catalogued as rs944211695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIPA1L1 | c.1671G>A p.P557= | Silent (SNP) | VAF 712/1659 reads (43%) | catalogued as rs767200443; called by muse, mutect2, varscan2
- SLC16A3 | c.756C>T p.Y252= | Silent (SNP) | VAF 160/354 reads (45%) | catalogued as rs756802723; called by muse, mutect2, varscan2
- SLC22A23 | c.1710C>T p.G570= | Silent (SNP) | VAF 205/508 reads (40%) | catalogued as rs756493746; called by muse, mutect2, varscan2
- SLC39A6 | c.288C>T p.H96= | Silent (SNP) | VAF 486/1229 reads (40%) | catalogued as rs543835187; called by muse, mutect2, varscan2
- SLC4A3 | c.1842C>T p.S614= | Silent (SNP) | VAF 304/735 reads (41%) | catalogued as rs553891640, COSV56091490; called by muse, mutect2, varscan2
- SNX27 | c.1596G>A p.A532= | Silent (SNP) | VAF 602/1450 reads (42%) | catalogued as rs765970268, COSV64327384; called by muse, mutect2, varscan2
- SP5 | c.843G>A p.A281= | Silent (SNP) | VAF 63/596 reads (11%) | called by muse, mutect2, varscan2
- SPTBN2 | c.1563C>T p.A521= | Silent (SNP) | VAF 74/601 reads (12%) | catalogued as rs370685694; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRRM5 | c.2145G>A p.A715= | Silent (SNP) | VAF 218/533 reads (41%) | catalogued as rs377174455; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.537G>A p.T179= | Silent (SNP) | VAF 122/863 reads (14%) | catalogued as COSV50074980; called by muse, mutect2, varscan2
- SYNGAP1 | c.1572C>T p.C524= | Silent (SNP) | VAF 217/1049 reads (21%) | catalogued as rs763080466, COSV99538923; called by muse, mutect2, varscan2
- TCP11L2 | c.861C>T p.A287= | Silent (SNP) | VAF 200/1763 reads (11%) | catalogued as rs201680467; called by muse, mutect2, varscan2
- TECR | c.711G>A p.T237= | Silent (SNP) | VAF 194/651 reads (30%) | called by muse, mutect2, varscan2
- TENM4 | c.2898C>T p.G966= | Silent (SNP) | VAF 552/2215 reads (25%) | catalogued as rs770397552, COSV53614706; called by muse, mutect2, varscan2
- TERT | c.2565G>A p.A855= | Silent (SNP) | VAF 138/1601 reads (9%) | catalogued as rs769077049, COSV57217392, COSV57244316; ClinVar: likely benign; called by muse, mutect2
- THAP4 | c.870C>T p.T290= | Silent (SNP) | VAF 146/356 reads (41%) | catalogued as rs773652037; called by muse, mutect2, varscan2
- TMC4 | c.1614G>A p.A538= (on ENST00000617472 / NM_001145303.3; = p.A532= on NM_144686.4) | Silent (SNP) | VAF 70/945 reads (7%) | catalogued as rs1167711728, COSV99714075; called by muse, mutect2
- TMEM201 | c.900C>T p.V300= | Silent (SNP) | VAF 373/866 reads (43%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.1161G>A p.P387= (on ENST00000452346; = p.P261= on NM_001042575.2) | Silent (SNP) | VAF 553/1347 reads (41%) | catalogued as rs755021614, COSV69981630; called by muse, mutect2, varscan2
- TNRC18 | c.3531G>A p.S1177= | Silent (SNP) | VAF 113/412 reads (27%) | catalogued as rs759862171; called by muse, mutect2, varscan2
- TRIM14 | c.957C>T p.T319= | Silent (SNP) | VAF 56/432 reads (13%) | called by muse, mutect2, varscan2
- TRIM42 | c.963C>T p.H321= | Silent (SNP) | VAF 588/1462 reads (40%) | catalogued as rs973883247, COSV53880614; called by muse, varscan2
- TRIM64C | c.594G>A p.L198= | Silent (SNP) | VAF 204/2407 reads (8%) | catalogued as rs1565098247; called by muse, mutect2
- TRPM2 | c.2355G>A p.A785= | Silent (SNP) | VAF 236/570 reads (41%) | catalogued as rs755300131; called by muse, mutect2, varscan2
- TSHZ3 | c.1893G>A p.P631= | Silent (SNP) | VAF 229/560 reads (41%) | catalogued as rs202193828, COSV53666897; called by muse, mutect2, varscan2
- TTN | c.85305G>A p.T28435= (on ENST00000591111; = p.T21011= on NM_003319.4) | Silent (SNP) | VAF 606/1585 reads (38%) | catalogued as rs778516869; called by muse, mutect2, varscan2
- VASP | c.336G>A p.A112= | Silent (SNP) | VAF 180/508 reads (35%) | catalogued as rs142140615; called by muse, mutect2, varscan2
- VSIG10 | c.984G>A p.T328= | Silent (SNP) | VAF 458/993 reads (46%) | catalogued as rs761568859, COSV63653053; called by muse, mutect2, varscan2
- XPOT | c.1410T>C p.G470= | Silent (SNP) | VAF 783/1819 reads (43%) | called by muse, mutect2, varscan2
- YWHAE | c.624G>A p.T208= | Silent (SNP) | VAF 105/1582 reads (7%) | catalogued as rs773680034; called by muse, mutect2
- ZFHX2 | c.2685C>T p.R895= | Silent (SNP) | VAF 36/482 reads (7%) | catalogued as rs538736105, COSV69493669; called by muse, mutect2
- ZFHX3 | c.7128G>A p.T2376= | Silent (SNP) | VAF 354/894 reads (40%) | catalogued as rs776815322, COSV99215540; called by muse, varscan2
- ZNF136 | c.1545C>T p.C515= | Silent (SNP) | VAF 404/1054 reads (38%) | called by muse, mutect2, varscan2
- ZNF175 | c.786C>T p.G262= | Silent (SNP) | VAF 346/708 reads (49%) | called by muse, mutect2, varscan2
- ZNF213 | c.420G>A p.A140= | Silent (SNP) | VAF 468/1034 reads (45%) | catalogued as rs374611671; called by muse, mutect2, varscan2
- ZNF433 | c.177C>T p.Y59= | Silent (SNP) | VAF 105/1292 reads (8%) | catalogued as rs200983088; called by muse, mutect2
- ZNF629 | c.2259C>T p.S753= | Silent (SNP) | VAF 52/547 reads (10%) | catalogued as rs201778896; called by muse, mutect2
- ZSCAN10 | c.1569C>T p.Y523= (on ENST00000252463; = p.Y578= on NM_032805.3) | Silent (SNP) | VAF 56/496 reads (11%) | catalogued as COSV52966653; called by muse, mutect2, varscan2
- ZSWIM9 | c.660G>A p.A220= | Silent (SNP) | VAF 96/730 reads (13%) | catalogued as rs1407514826; called by muse, mutect2, varscan2
- ABCB10 | c.*61del | 3'UTR (DEL) | VAF 97/210 reads (46%) | catalogued as rs895741052; called by mutect2, varscan2
- ADAM15 | c.*51C>T | 3'UTR (SNP) | VAF 111/628 reads (18%) | catalogued as rs780417758, COSV99665196; called by muse, mutect2, varscan2
- ADAM8 | c.1107-31C>T | Intron (SNP) | VAF 125/156 reads (80%) | catalogued as rs777350567; called by muse, mutect2, varscan2
- ANAPC2 | c.740+48C>T | Intron (SNP) | VAF 78/136 reads (57%) | catalogued as rs1242078713; called by muse, mutect2, varscan2
- ANKMY1 | c.-73G>A | 5'UTR (SNP) | VAF 416/1027 reads (41%) | catalogued as rs771187106; called by muse, mutect2, varscan2
- ANKRD33 | c.-110dup | 5'UTR (INS) | VAF 113/524 reads (22%) | called by mutect2, varscan2
- APBA3 | c.1011+15C>T | Intron (SNP) | VAF 60/326 reads (18%) | catalogued as rs763111899; called by muse, varscan2
- APOH | c.-18C>A | 5'UTR (SNP) | VAF 141/1316 reads (11%) | called by muse, mutect2, varscan2
- APP | c.*31C>T | 3'UTR (SNP) | VAF 38/789 reads (5%) | called by muse, mutect2
- ARFGAP2 | c.264+12_264+14del | Intron (DEL) | VAF 156/374 reads (42%) | called by mutect2, varscan2
- ARHGAP45 | c.1829-15C>T | Intron (SNP) | VAF 161/314 reads (51%) | catalogued as rs1335068484; called by muse, mutect2, varscan2
- B3GAT1 | c.113-21G>A | Intron (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- BAG6 | c.3426+78C>T | Intron (SNP) | VAF 111/224 reads (50%) | catalogued as rs1305944784; called by muse, mutect2, varscan2
- BAZ1A | c.1511-93C>T | Intron (SNP) | VAF 23/72 reads (32%) | catalogued as rs989000003; called by muse, mutect2, varscan2
- BRD7 | c.-28G>A | 5'UTR (SNP) | VAF 113/340 reads (33%) | called by muse, mutect2, varscan2
- C17orf67 | c.157-64C>T | Intron (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
- C20orf27 | c.19+44G>A | Intron (SNP) | VAF 352/775 reads (45%) | catalogued as rs367559490; called by muse, mutect2, varscan2
- CALB1 | c.507-30T>A | Intron (SNP) | VAF 138/929 reads (15%) | called by muse, mutect2, varscan2
- CCDC12 | c.341+13C>T | Intron (SNP) | VAF 293/1110 reads (26%) | catalogued as rs746074966; called by muse, mutect2, varscan2
- CCDC142 | c.1618+23_1618+25del | Intron (DEL) | VAF 56/388 reads (14%) | catalogued as rs773415456; called by mutect2, varscan2
- CCDC85C | c.*4440del | 3'UTR (DEL) | VAF 186/420 reads (44%) | called by mutect2, varscan2
- CD79B | c.*98dup | 3'UTR (INS) | VAF 26/66 reads (39%) | catalogued as rs968665622; called by mutect2, varscan2
- CDC23 | c.*72C>T | 3'UTR (SNP) | VAF 167/201 reads (83%) | catalogued as rs1194793957; called by muse, mutect2, varscan2
- CEP290 | c.6960+48G>A | Intron (SNP) | VAF 224/571 reads (39%) | catalogued as rs375563137; called by muse, mutect2, varscan2
- CLDN18 | c.*57dup | 3'UTR (INS) | VAF 134/344 reads (39%) | catalogued as rs778117984; called by mutect2, varscan2
- CLEC9A | c.*84dup | 3'UTR (INS) | VAF 118/350 reads (34%) | catalogued as rs1555153509; called by mutect2, varscan2
- CNTN3 | c.*51del | 3'UTR (DEL) | VAF 191/448 reads (43%) | catalogued as rs1386588716; called by mutect2, varscan2
- COL4A2 | c.1340-332C>T | Intron (SNP) | VAF 114/896 reads (13%) | called by muse, varscan2
- CREB5 | c.*43C>T | 3'UTR (SNP) | VAF 297/667 reads (45%) | catalogued as rs771427752; called by muse, mutect2, varscan2
- CSNK1D | c.737-70C>T | Intron (SNP) | VAF 67/137 reads (49%) | catalogued as rs947676564; called by muse, mutect2, varscan2
- CSNK1G2 | c.299-18G>A | Intron (SNP) | VAF 72/806 reads (9%) | catalogued as rs373031517; called by muse, mutect2
- DAGLA | c.*12C>T | 3'UTR (SNP) | VAF 17/385 reads (4%) | catalogued as rs1173372620; called by muse, mutect2
- DAZAP1 | c.*4G>A | 3'UTR (SNP) | VAF 165/384 reads (43%) | catalogued as rs369368411; called by muse, mutect2, varscan2
- DCK | c.*60G>A | 3'UTR (SNP) | VAF 173/834 reads (21%) | catalogued as rs756465115; called by muse, mutect2, varscan2
- DHX15 | c.1786+27del | Intron (DEL) | VAF 312/1576 reads (20%) | called by mutect2, varscan2
- DHX57 | c.1906-43del | Intron (DEL) | VAF 116/798 reads (15%) | catalogued as rs773146037; called by mutect2, varscan2
- DNMT3A | c.856-41C>T | Intron (SNP) | VAF 152/343 reads (44%) | catalogued as rs773331757; called by muse, mutect2, varscan2
- DPF1 | c.380-17del | Intron (DEL) | VAF 235/616 reads (38%) | catalogued as rs754640668; called by mutect2, varscan2
- DPP9 | c.2244+309G>A | Intron (SNP) | VAF 182/398 reads (46%) | catalogued as rs924325072, COSV53592144; called by muse, mutect2, varscan2
- DPP9 | c.2244+216G>A | Intron (SNP) | VAF 16/542 reads (3%) | catalogued as rs1480847864; called by muse, mutect2
- DRP2 | c.1054+90C>T | Intron (SNP) | VAF 102/114 reads (89%) | called by muse, mutect2, varscan2
- E4F1 | c.1935+22C>T | Intron (SNP) | VAF 201/481 reads (42%) | catalogued as rs200467051; called by muse, mutect2, varscan2
- ECHDC2 | c.801+21G>A | Intron (SNP) | VAF 109/808 reads (13%) | called by muse, mutect2, varscan2
- EFNA5 | c.418+60del | Intron (DEL) | VAF 56/138 reads (41%) | catalogued as rs770640003; called by mutect2, varscan2
- EIF3I | c.184+46C>T | Intron (SNP) | VAF 175/364 reads (48%) | catalogued as rs373564398; called by muse, mutect2, varscan2
- EIF5A | c.165+17C>T | Intron (SNP) | VAF 255/626 reads (41%) | catalogued as rs765739781; called by muse, mutect2, varscan2
- ELP2 | c.289-32dup | Intron (INS) | VAF 137/387 reads (35%) | catalogued as rs34817357; called by mutect2, varscan2
- EP300 | c.4780-20dup | Intron (INS) | VAF 42/318 reads (13%) | catalogued as rs749725027; called by mutect2, varscan2
- FAAP20 | c.470+602C>T | Intron (SNP) | VAF 41/308 reads (13%) | called by muse, mutect2, varscan2
- FAM162B | c.-50C>T | 5'UTR (SNP) | VAF 183/424 reads (43%) | catalogued as rs1212818803; called by muse, mutect2, varscan2
- FAM86B1 | c.790+37C>T | Intron (SNP) | VAF 113/1566 reads (7%) | catalogued as rs527915557, COSV100392123; called by muse, mutect2
- FDXR | c.178-1788G>A | Intron (SNP) | VAF 42/328 reads (13%) | catalogued as rs921144665, COSV53121410; called by muse, mutect2, varscan2
- GAS6 | c.1883-59del | Intron (DEL) | VAF 30/113 reads (27%) | catalogued as rs921514421; called by mutect2, varscan2
- GLB1L | c.-30G>A | 5'UTR (SNP) | VAF 38/450 reads (8%) | catalogued as COSV55478303; called by muse, mutect2
94 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 94 other) are not listed here.
